Somatic mutation profile of tumor specimen TCGA-EL-A3CN-01A (aliquot TCGA-EL-A3CN-01A-12D-A20C-08) from TCGA case TCGA-EL-A3CN, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 47.8 years (17,456 days).
Specimen TCGA-EL-A3CN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2774cecc-df7a-4fa6-aa7e-ac7ca7237b3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CN-10A (Blood Derived Normal), aliquot TCGA-EL-A3CN-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/959e6351-e398-48e0-9cca-48c29301c62a

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs1404157814, COSV56473315; called by muse, mutect2, varscan2
- ATP7B | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs183365083, CM136607, COSV54441936; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C3 | c.2355-1G>T p.X785_splice | Splice Site (SNP) | VAF 32/86 reads (37%) | catalogued as COSV55578689; called by muse, mutect2, varscan2
- CACNA1G | c.3812G>A p.R1271Q | Missense Mutation (SNP) | VAF 99/320 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs780733290, COSV61726837, COSV61734774; called by muse, mutect2, varscan2
- CENPI | c.982A>T p.S328C | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.72); catalogued as COSV54505176; called by muse, mutect2, varscan2
- DAAM1 | c.917A>G p.Y306C | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV62838747; called by muse, mutect2, varscan2
- DEUP1 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV53215227; called by muse, mutect2, varscan2
- MYLK | c.3901C>T p.R1301C | Missense Mutation (SNP) | VAF 45/382 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs368321325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1 | c.8671C>T p.R2891C | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs148990124; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3GLB2 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 79/265 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV65329959, COSV65331659; called by muse, mutect2, varscan2
- STOX2 | c.720C>A p.S240R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV57854981; called by muse, mutect2
- OR11G2 | c.585G>A p.L195= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV62132058, COSV62132890; called by muse, mutect2, varscan2
- RYR1 | c.3495C>T p.G1165= | Silent (SNP) | VAF 15/169 reads (9%) | catalogued as rs772616442, COSV100615741, COSV62101838; ClinVar: uncertain significance; called by muse, mutect2
